Somatic mutation profile of tumor specimen TCGA-60-2721-01A (aliquot TCGA-60-2721-01A-01D-1522-08) from TCGA case TCGA-60-2721, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.9 years (27,007 days).
Specimen TCGA-60-2721-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00c8b8f5-862d-401a-9d1a-117feb95a8ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2721-11A (Solid Tissue Normal), aliquot TCGA-60-2721-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a42496-3c52-4c12-acd3-c4e1fa74a307

The open-access MAF lists 206 somatic variants for this specimen: 151 protein-altering or splice-affecting, 45 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 45, Nonsense Mutation 16, Frame Shift Del 5, Splice Site 5, Intron 3, RNA 3, 5'Flank 2, Splice Region 2, 3'UTR 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 23/188 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3314G>T p.C1105F (on ENST00000404938 / NM_001163941.2; = p.C660F on NM_178559.6) | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV51702598; called by muse, mutect2, varscan2
- ABL2 | c.896A>G p.Y299C (on ENST00000502732 / NM_007314.4; = p.Y284C on NM_005158.5) | Missense Mutation (SNP) | VAF 141/364 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777388022, COSV61010828; called by muse, mutect2, varscan2
- ACSM2A | c.1346T>C p.I449T (on ENST00000219054; = p.I370T on NM_001308169.2) | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.113); catalogued as rs754805512, COSV54581876; called by muse, mutect2, varscan2
- ACSM2B | c.1346T>C p.I449T | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.113); catalogued as rs771113405, COSV100312994; called by muse, mutect2
- ACSM5 | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV59369360; called by muse, mutect2, varscan2
- ACTL6B | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs1431929583, COSV99355685; called by mutect2, varscan2
- ADGRB3 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV100999511, COSV65381041; called by muse, mutect2, varscan2
- AFG3L2 | c.1245G>C p.K415N | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV52312602; called by muse, mutect2, varscan2
- AHSG | c.893A>T p.H298L | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs779306798, COSV99890213; called by muse, mutect2, varscan2
- ALKBH6 | c.203G>C p.R68P (on ENST00000252984 / NM_001297701.2; = p.R96P on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99431054, COSV99431236; called by muse, mutect2, varscan2
- ALKBH8 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52833196; called by muse, mutect2, varscan2
- ANKH | c.333C>G p.Y111* | Nonsense Mutation (SNP) | VAF 59/226 reads (26%) | catalogued as COSV52476319; called by muse, mutect2, varscan2
- ANKRD11 | c.4349C>T p.S1450F | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV99970166; called by muse, mutect2
- ANKRD30A | c.3769C>T p.Q1257* (on ENST00000611781; = p.Q1201* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100653303; called by muse, mutect2, varscan2
- AP1S3 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100525366, COSV57510874; called by muse, mutect2, varscan2
- APOC2 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52989861; called by muse, mutect2, varscan2
- ARHGAP12 | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60960956; called by muse, mutect2, varscan2
- ARMC4 | c.1414G>C p.A472P | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59455261; called by muse, mutect2, varscan2
- ART3 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100587887; called by muse, mutect2
- ATP2A2 | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.015); catalogued as rs746403445, COSV100428800; called by muse, mutect2, varscan2
- ATXN2 | c.1466+2T>A p.X489_splice (on ENST00000550104; = p.X329_splice on NM_002973.4) | Splice Site (SNP) | VAF 92/342 reads (27%) | catalogued as COSV66481004; called by muse, varscan2
- B4GALT6 | c.146G>C p.R49P | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV52702466; called by muse, mutect2, varscan2
- BMP2K | c.2589C>G p.F863L | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99785326; called by muse, mutect2, varscan2
- BNIP1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1308296048, COSV99199428; called by muse, mutect2
- BPIFB4 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV64950595; called by muse, mutect2, varscan2
- BRD8 | c.3286C>G p.L1096V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.129); catalogued as rs1368826324, COSV99647699, COSV99648790; called by muse, mutect2, varscan2
- C1orf74 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.536); catalogued as COSV50550411; called by muse, mutect2, varscan2
- CACNA2D1 | c.1516-2A>G p.X506_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100666996; called by muse, mutect2, varscan2
- CACNB3 | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV56396963; called by muse, mutect2, varscan2
- CARD8 | c.1175C>G p.S392C (on ENST00000651546 / NM_001184900.3; = p.S342C on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV100751173; called by muse, mutect2, varscan2
- CC2D1B | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52558442; called by muse, mutect2, varscan2
- CCNB1IP1 | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100738617; called by muse, mutect2
- CDC25B | c.1216G>T p.D406Y (on ENST00000245960 / NM_021873.3; = p.D392Y on NM_004358.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99848219; called by muse, mutect2, varscan2
- CEL | c.1444A>G p.T482A (on ENST00000673714; = p.T479A on NM_001807.6) | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV60826168; called by muse, mutect2, varscan2
- CNOT1 | c.4918C>T p.R1640* | Nonsense Mutation (SNP) | VAF 14/217 reads (6%) | catalogued as COSV55314883; called by muse, mutect2
- CSMD3 | c.9564T>A p.D3188E (on ENST00000297405 / NM_001363185.1; = p.D3019E on NM_052900.3) | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99842057; called by muse, mutect2
- CSPG4 | c.4507G>A p.D1503N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371941921; called by muse, mutect2, varscan2
- DHRS7C | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57649526; called by muse, mutect2, varscan2
- DHX37 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100439518, COSV58131501; called by muse, mutect2, varscan2
- DIRAS1 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60214905; called by muse, mutect2, varscan2
- DNM1 | c.1584C>G p.I528M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57848589; called by muse, mutect2, varscan2
- DOCK10 | c.3206G>C p.R1069P | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99287542, COSV99291510; called by muse, mutect2
- DPP10 | c.1810A>G p.S604G | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.565); catalogued as COSV59661662; called by muse, mutect2, varscan2
- EEF2K | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV53778258; called by muse, mutect2, varscan2
- ETV6 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67148028; called by muse, mutect2, varscan2
- EYA2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100427148; called by muse, mutect2, varscan2
- EZR | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 9/152 reads (6%) | catalogued as COSV100455040; called by muse, mutect2
- FAM237A | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.014); catalogued as rs368340742; called by muse, mutect2, varscan2
- FBXL20 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 15/205 reads (7%) | catalogued as COSV99234541; called by muse, mutect2
- FUT5 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV53134602; called by muse, mutect2, varscan2
- GALNT13 | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101221730, COSV67208917, COSV67220147; called by muse, mutect2, varscan2
- GALNT7 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | catalogued as COSV53929000, COSV99397646; called by muse, mutect2
- GBGT1 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs976139003, COSV64409895; called by muse, mutect2, varscan2
- GBP3 | c.1785C>G p.I595M | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV52518428, COSV99352663; called by muse, mutect2
- GRHL1 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 78/441 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100258027, COSV61411495; called by muse, mutect2, varscan2
- HDAC1 | c.1188G>C p.E396D | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.314); catalogued as rs919056789, COSV61481785; called by muse, mutect2, varscan2
- HECTD4 | c.10287G>C p.E3429D | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.995); catalogued as COSV101108146; called by muse, mutect2
- INSIG1 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV60919629; called by muse, mutect2, varscan2
- INTS8 | c.2384A>G p.H795R | Missense Mutation (SNP) | VAF 68/311 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV58248379; called by muse, mutect2, varscan2
- KCNA1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.043); catalogued as COSV101230315, COSV66836858; called by muse, mutect2
- KCNJ2 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1234083049, COSV54663366, COSV99696460; called by muse, mutect2
- KCNN1 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55836787; called by muse, mutect2, varscan2
- KHSRP | c.474G>T p.L158= | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as COSV67919327; called by muse, mutect2, varscan2
- KIFAP3 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100847057; called by muse, mutect2, varscan2
- KIR2DL1 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV99383459; called by muse, mutect2
- KLRB1 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV57589135; called by muse, mutect2, varscan2
- KRI1 | c.1026G>C p.E342D | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100470304; called by muse, varscan2
- KRT23 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52926938; called by muse, mutect2, varscan2
- KTI12 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV65405549; called by muse, mutect2, varscan2
- LPA | c.5075G>A p.R1692Q | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV60304580; called by muse, mutect2, varscan2
- LRRC37A3 | c.3278C>G p.S1093* | Nonsense Mutation (SNP) | VAF 60/592 reads (10%) | catalogued as COSV100140859, COSV100141328; called by muse, mutect2
- LSR | c.1736C>G p.S579C (on ENST00000361790; = p.S560C on NM_015925.6) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV55887969; called by muse, mutect2
- M6PR | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1565530467, COSV50002502; called by muse, mutect2, varscan2
- MAGIX | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 108/187 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV66255633; called by muse, mutect2, varscan2
- MCF2 | c.2669A>G p.E890G | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100644964; called by muse, mutect2
- MEIOC | c.861C>G p.I287M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as COSV100740275, COSV63440046; called by muse, mutect2, varscan2
- MTERF3 | c.488-1G>C p.X163_splice | Splice Site (SNP) | VAF 29/133 reads (22%) | catalogued as COSV54631703; called by muse, mutect2, varscan2
- MYO1E | c.1318T>A p.Y440N | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99896258; called by muse, mutect2, varscan2
- NEBL | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755632954, COSV65799454; called by muse, mutect2, varscan2
- NLRP1 | c.3860G>A p.G1287D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407715631, COSV52557740; called by muse, mutect2, varscan2
- NPR1 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64140175; called by muse, mutect2, varscan2
- NT5C3A | c.515C>G p.S172C (on ENST00000610140 / NM_001374335.1; = p.S138C on NM_016489.13) | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54239084, COSV99641300; called by muse, mutect2
- NUF2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV54841894; called by muse, mutect2, varscan2
- NUP210L | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55142893; called by muse, varscan2
- OR2L13 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63547572; called by muse, mutect2, varscan2
- OR2M2 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 68/510 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs754505341, COSV100677281; called by muse, mutect2, varscan2
- OR2W1 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101013900, COSV101013928; called by muse, mutect2
- PABPC3 | c.1740G>T p.L580F | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99879758; called by muse, mutect2
- PABPC5 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV57038971, COSV57039392; called by muse, mutect2, varscan2
- PAK5 | c.2004G>A p.K668= | Splice Region (SNP) | VAF 79/346 reads (23%) | catalogued as COSV62020218; called by muse, mutect2, varscan2
- PCNX2 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.133); catalogued as COSV99268798; called by muse, mutect2
- PEG3 | c.3292C>A p.Q1098K | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV55623726; called by muse, mutect2, varscan2
- PFKFB1 | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | PolyPhen benign (0.167); catalogued as COSV99436985; called by muse, mutect2
- PGD | c.1109G>C p.S370T | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54620101; called by muse, mutect2, varscan2
- PGM2L1 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53345922; called by muse, mutect2
- PHF3 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs774095026, COSV50312966, COSV50322278; called by muse, mutect2, varscan2
- PIWIL3 | c.747G>C p.K249N | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100177840; called by muse, mutect2
- PKHD1L1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs202179223, COSV65751623; called by muse, mutect2, varscan2
- PLEKHG3 | c.679C>T p.Q227* (on ENST00000394691; = p.Q283* on NM_001308147.2) | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV55977343; called by muse, mutect2
- PPP1R15A | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1463264191, COSV52338245; called by muse, mutect2, varscan2
- PPP2R5D | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV100028911; called by muse, mutect2
- RALGAPA1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs1196230797, COSV99355552; called by muse, mutect2, varscan2
- RASD2 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs766683427, COSV99332860; called by muse, mutect2, varscan2
- REST | c.2891C>G p.S964* | Nonsense Mutation (SNP) | VAF 16/137 reads (12%) | catalogued as COSV100471217, COSV58361238; called by muse, mutect2, varscan2
- REV3L | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs1451533465, COSV100725513; called by muse, mutect2
- RHBDD1 | c.851A>G p.D284G | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV100392069; called by muse, mutect2, varscan2
- RPS6KA1 | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1223331310, COSV64809534; called by muse, mutect2, varscan2
- RTL4 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771672393, COSV100466063; called by muse, mutect2
- SAMD1 | c.1298G>C p.*433Sext*84 | Nonstop Mutation (SNP) | VAF 28/162 reads (17%) | catalogued as COSV99513878, COSV99513905; called by muse, mutect2, varscan2
- SEC14L1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV66720731; called by muse, mutect2, varscan2
- SEC22A | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100007097; called by muse, mutect2, varscan2
- SLC15A4 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 63/189 reads (33%) | catalogued as COSV57160203; called by muse, mutect2, varscan2
- SLX4IP | c.539C>G p.T180R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV57943602, COSV57952245; called by muse, mutect2
- SPATA31D1 | c.3655C>T p.Q1219* | Nonsense Mutation (SNP) | VAF 21/282 reads (7%) | catalogued as COSV100782933; called by muse, mutect2
- TCN2 | c.963G>C p.E321D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV99308697; called by muse, mutect2
- TEKT5 | c.887C>G p.A296G | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV51586406; called by muse, mutect2, varscan2
- TENM1 | c.8013G>T p.E2671D | Missense Mutation (SNP) | VAF 145/277 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV64424340; called by muse, mutect2, varscan2
- TFR2 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as COSV56152850; called by muse, mutect2, varscan2
- TG | c.6454G>C p.V2152L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV55064201; called by muse, mutect2, varscan2
- TM6SF2 | c.940A>G p.M314V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs368032431, COSV52268269; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV100836164; called by muse, mutect2
- TNRC6A | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59360388; called by muse, mutect2, varscan2
- TNS3 | c.587-2A>G p.X196_splice | Splice Site (SNP) | VAF 34/158 reads (22%) | catalogued as COSV60786405; called by muse, varscan2
- TOGARAM1 | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV100753207; called by muse, mutect2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TRERF1 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.145); catalogued as COSV100550587, COSV100551278; called by muse, mutect2, varscan2
- TSSK3 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100344936, COSV61982706; called by muse, mutect2, varscan2
- TTLL2 | c.646T>A p.L216I | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV53442464; called by muse, mutect2, varscan2
- TTN | c.52945G>C p.D17649H (on ENST00000591111; = p.D10225H on NM_003319.4) | Missense Mutation (SNP) | VAF 37/236 reads (16%) | PolyPhen probably damaging (0.999); catalogued as rs770980138, COSV100622974; called by muse, mutect2, varscan2
- TUBA3C | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 115/227 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); catalogued as rs1390210163, COSV68027449; called by muse, mutect2, varscan2
- UBR5 | c.8204C>G p.S2735* | Nonsense Mutation (SNP) | VAF 4/78 reads (5%) | catalogued as COSV99641782; called by muse, mutect2
- USP29 | c.576C>G p.N192K | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54139619; called by muse, mutect2, varscan2
- WDR92 | c.128C>G p.T43S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99718406; called by muse, mutect2, varscan2
- XKR5 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV101306728; called by muse, mutect2
- ZMYM2 | c.3184G>C p.D1062H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as COSV101243972, COSV67033737; called by muse, mutect2
- ZNF175 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99219670; called by muse, mutect2
- ZNF175 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.076); catalogued as COSV51796133, COSV51796687; called by muse, mutect2
- ZNF491 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV100022006; called by muse, mutect2, varscan2
- ZNF582 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.621); catalogued as COSV56731270, COSV56731993; called by muse, mutect2, varscan2
- ZP4 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100850625, COSV100850742; called by muse, mutect2
- ASAH2 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CASZ1 | c.2409del p.I804Yfs*73 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- IGKV1-12 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 71/677 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGKV4-1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2C | c.2985del p.V996Wfs*35 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- MRC1 | c.3250+1G>A p.X1084_splice | Splice Site (SNP) | VAF 60/208 reads (29%) | called by mutect2, varscan2
- OR2M2 | c.453_454delinsT p.G152Afs*10 | Frame Shift Del (DEL) | VAF 53/556 reads (10%) | called by pindel, varscan2*
- RHO | c.512del p.P171Hfs*46 | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | called by mutect2, varscan2
- VPS50 | c.1747del p.S583Vfs*7 | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | called by mutect2, pindel, varscan2
- AADAC | c.69C>G p.L23= | Silent (SNP) | VAF 45/336 reads (13%) | catalogued as COSV99233417; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.495C>T p.L165= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs763747750, COSV100416717, COSV58445823; called by muse, mutect2
- ADGRA2 | c.3156C>T p.C1052= | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as COSV55102504; called by muse, mutect2, varscan2
- AHNAK2 | c.12738A>G p.K4246= | Silent (SNP) | VAF 22/406 reads (5%) | catalogued as rs200545098, COSV100318411; called by muse, mutect2
- ANKRD11 | c.6195C>T p.F2065= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1334128223, COSV56363105, COSV99970157; called by muse, mutect2
- APLF | c.903T>C p.L301= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV58142226; called by muse, mutect2, varscan2
- AR | c.1962G>A p.E654= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV65952668; called by muse, mutect2, varscan2
- BAIAP2L1 | c.654G>C p.L218= | Silent (SNP) | VAF 12/447 reads (3%) | called by muse, mutect2
- CELF5 | c.1428G>A p.K476= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1228836892, COSV53010084; called by muse, mutect2, varscan2
- CEP135 | c.891C>T p.T297= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV57257873; called by muse, mutect2, varscan2
- COP1 | c.1542G>A p.K514= | Silent (SNP) | VAF 18/301 reads (6%) | catalogued as rs1041415266, COSV100443681; ClinVar: likely benign; called by muse, mutect2
- CPT1A | c.1335C>T p.H445= | Silent (SNP) | VAF 104/447 reads (23%) | catalogued as rs768418242, COSV55752417, COSV55753514; called by muse, mutect2, varscan2
- EPB41L3 | c.1731G>A p.Q577= | Silent (SNP) | VAF 11/159 reads (7%) | catalogued as COSV100549844, COSV99048679; called by muse, mutect2
- EPHB6 | c.2910C>T p.F970= | Silent (SNP) | VAF 56/263 reads (21%) | catalogued as COSV63890283; called by muse, mutect2, varscan2
- FGF11 | c.213C>T p.I71= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs969208480, COSV99548449; called by muse, mutect2, varscan2
- FRG2C | c.117A>C p.P39= | Silent (SNP) | VAF 66/578 reads (11%) | called by muse, mutect2, varscan2
- IGLC3 | c.228T>G p.P76= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- IQUB | c.702T>C p.D234= | Silent (SNP) | VAF 8/226 reads (4%) | catalogued as COSV100227251; called by muse, mutect2
- IREB2 | c.2220C>G p.A740= | Silent (SNP) | VAF 103/448 reads (23%) | catalogued as COSV51920361; called by muse, mutect2, varscan2
- KIAA1109 | c.12984C>T p.S4328= | Silent (SNP) | VAF 58/108 reads (54%) | catalogued as COSV52661569, COSV99169518; called by muse, mutect2, varscan2
- LNP1 | c.453G>A p.K151= | Silent (SNP) | VAF 9/238 reads (4%) | catalogued as COSV101051325; called by muse, mutect2
- MCC | c.213G>A p.E71= | Silent (SNP) | VAF 26/205 reads (13%) | catalogued as COSV101342734; called by muse, mutect2, varscan2
- METAP1D | c.921C>T p.D307= | Silent (SNP) | VAF 65/263 reads (25%) | catalogued as COSV59928738; called by muse, mutect2, varscan2
- MTUS2 | c.2358G>C p.L786= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV101462309; called by muse, mutect2
- NFS1 | c.882G>T p.G294= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100931984; called by muse, mutect2, varscan2
- NYX | c.1107C>T p.A369= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1172461121, COSV61180165; called by muse, mutect2, varscan2
- OR2B2 | c.127C>T p.L43= | Silent (SNP) | VAF 58/151 reads (38%) | catalogued as COSV57579025; called by muse, mutect2, varscan2
- OR2T12 | c.870G>A p.V290= | Silent (SNP) | VAF 32/423 reads (8%) | catalogued as COSV58776986; called by muse, mutect2
- OR9G4 | c.867C>T p.I289= | Silent (SNP) | VAF 17/280 reads (6%) | catalogued as COSV100265203; called by muse, mutect2
- PER3 | c.1863G>C p.L621= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100728423; called by muse, mutect2
- PKHD1 | c.2970T>G p.V990= | Silent (SNP) | VAF 81/237 reads (34%) | catalogued as COSV61859112; called by muse, mutect2, varscan2
- PLEKHG3 | c.2949C>G p.L983= (on ENST00000394691; = p.L1039= on NM_001308147.2) | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as rs1333158337, COSV55977352; called by muse, mutect2, varscan2
- PUS1 | c.633G>T p.A211= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV59034723, COSV59036187; called by muse, mutect2, varscan2
- SDF4 | c.738C>T p.L246= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs752317746, COSV55417506; called by muse, mutect2, varscan2
- SLC15A4 | c.858C>G p.V286= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as rs1338162531, COSV57160198; called by muse, mutect2, varscan2
- SLC44A4 | c.651C>T p.I217= | Silent (SNP) | VAF 14/177 reads (8%) | catalogued as COSV99999142; called by muse, mutect2
- SOX13 | c.1140C>T p.L380= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as rs754705581, COSV65826192; called by muse, mutect2, varscan2
- STAU1 | c.225A>G p.V75= | Silent (SNP) | VAF 67/274 reads (24%) | catalogued as COSV61458685; called by muse, mutect2, varscan2
- TAAR2 | c.312G>T p.S104= (on ENST00000367931 / NM_001033080.1; = p.S59= on NM_014626.3) | Silent (SNP) | VAF 54/168 reads (32%) | catalogued as COSV51578358; called by muse, mutect2, varscan2
- VN1R1 | c.450C>G p.L150= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as COSV100320750; called by muse, mutect2, varscan2
- VSNL1 | c.303G>A p.L101= | Silent (SNP) | VAF 11/251 reads (4%) | catalogued as COSV99723249; called by muse, mutect2
- VWA3B | c.2796C>T p.R932= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV101346108, COSV68241684; called by muse, mutect2, varscan2
- ZDHHC9 | c.726G>T p.L242= | Silent (SNP) | VAF 71/138 reads (51%) | catalogued as COSV64096071, COSV64097506; called by muse, mutect2, varscan2
- ZNF398 | c.741C>G p.S247= (on ENST00000475153 / NM_170686.3; = p.S76= on NM_020781.4) | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV100246993; called by muse, mutect2
- ZNF562 | c.594C>G p.L198= (on ENST00000453372 / NM_001130032.2; = p.L126= on NM_017656.4) | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV53332539, COSV53335668; called by muse, mutect2, varscan2
- ADARB2 | c.1865-1490G>T | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- AKR1C8P | chr10:5185105 C>T | 5'Flank (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- AP001042.1 | n.2559C>G | RNA (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93733554 G>A | 3'Flank (SNP) | VAF 24/232 reads (10%) | catalogued as rs1192338320; called by muse, mutect2
- FAM183BP | n.996C>T | RNA (SNP) | VAF 34/137 reads (25%) | catalogued as rs772909023; called by muse, mutect2, varscan2
- GRIA3 | c.2440-2654G>C | Intron (SNP) | VAF 38/74 reads (51%) | catalogued as COSV52047901; called by muse, mutect2, varscan2
- HNRNPU | c.634+1006G>C | Intron (SNP) | VAF 35/762 reads (5%) | catalogued as COSV99310537; called by muse, mutect2
- LEKR1 | c.*745C>G | 3'UTR (SNP) | VAF 13/213 reads (6%) | catalogued as COSV100739209; called by muse, mutect2
- MIR519A1 | n.83G>C | RNA (SNP) | VAF 25/174 reads (14%) | catalogued as rs1234577233; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791162 A>T | 5'Flank (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
